Somatic mutation profile of tumor specimen TCGA-B2-4101-01A (aliquot TCGA-B2-4101-01A-02D-1458-08) from TCGA case TCGA-B2-4101, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 52.2 years (19,059 days).
Specimen TCGA-B2-4101-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2f304b5-8fee-4e59-be4a-7a1a5e608024.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-4101-11A (Solid Tissue Normal), aliquot TCGA-B2-4101-11A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de476f2e-851b-4160-983b-8c39c8ef5853

The open-access MAF lists 49 somatic variants for this specimen: 43 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 5, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.341-2A>T p.X114_splice | Splice Site (SNP) | VAF 60/228 reads (26%) | hotspot (GDC flag); catalogued as CS071275, COSV56542830, COSV56544966, COSV56548666, COSV56554645; called by muse, mutect2, varscan2
- AKT2 | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV60907576, COSV60910123; called by muse, mutect2, varscan2
- ARHGAP31 | c.4257G>C p.E1419D | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51788951, COSV51796184; called by muse, mutect2
- BCL11B | c.2390C>T p.T797M (on ENST00000357195 / NM_001282237.2; = p.T726M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61733099; called by muse, mutect2, varscan2
- C1orf52 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1191243586, COSV53998012; called by muse, mutect2
- CAMSAP3 | c.2354G>T p.R785L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50330782, COSV50331150; called by muse, mutect2, varscan2
- CCDC172 | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV60936563; called by muse, mutect2
- CDSN | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs374928892; called by muse, mutect2, varscan2
- CES1 | c.1132G>T p.A378S (on ENST00000361503 / NM_001025194.2; = p.A377S on NM_001266.5) | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.317); catalogued as COSV62085391; called by muse, mutect2
- COMMD5 | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV57382602; called by muse, mutect2, varscan2
- DDX50 | c.2020T>C p.S674P | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.91); catalogued as COSV65291685; called by muse, mutect2, varscan2
- DNAJC16 | c.1199A>C p.K400T | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV65448039; called by muse, mutect2
- DPYSL3 | c.516T>A p.D172E | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV58323887; called by muse, mutect2
- ETV4 | c.546-1G>A p.X182_splice | Splice Site (SNP) | VAF 26/130 reads (20%) | catalogued as COSV60043699; called by muse, mutect2, varscan2
- FAM170A | c.774C>A p.H258Q | Missense Mutation (SNP) | VAF 63/392 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58923853, COSV58925163; called by muse, mutect2, varscan2
- LRP2 | c.404A>G p.D135G | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55540415; called by muse, mutect2, varscan2
- MACROH2A2 | c.14G>C p.S5T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV64712304; called by muse, mutect2, varscan2
- MUC7 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.794); catalogued as COSV59216997; called by muse, mutect2, varscan2
- MYH13 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs201107300, COSV52820473, COSV52827079; called by muse, mutect2
- NUP160 | c.2428T>A p.L810I | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV65853442; called by muse, mutect2
- PBRM1 | c.580_581del p.V194Cfs*11 | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | catalogued as COSV56260661; called by mutect2, pindel, varscan2
- PCDHA10 | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 59/369 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.062); catalogued as rs782434219, COSV100249456, COSV56477018; called by muse, mutect2, varscan2
- PHLPP1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs779610862, COSV53021699; called by muse, mutect2, varscan2
- PTGS2 | c.464A>C p.K155T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as COSV66568250; called by muse, mutect2
- PTPN18 | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV51557980; called by muse, mutect2, varscan2
- RFT1 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56247960; called by muse, mutect2, varscan2
- RPL27 | c.338A>G p.E113G | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV53814486; called by muse, mutect2, varscan2
- SERPING1 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs775707002, COSV53541457; called by muse, mutect2, varscan2
- SETD2 | c.5158G>T p.E1720* | Nonsense Mutation (SNP) | VAF 23/150 reads (15%) | catalogued as COSV57429791, COSV57447120; called by muse, mutect2, varscan2
- SLC35F1 | c.293T>C p.F98S | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV64498571; called by muse, mutect2
- SMG8 | c.2908C>G p.P970A | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141411025; called by muse, mutect2, varscan2
- TACC2 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.153); catalogued as rs540521848, COSV57745865; called by muse, mutect2, varscan2
- TAS2R60 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 43/209 reads (21%) | catalogued as COSV60329993; called by muse, mutect2, varscan2
- THSD7B | c.4363G>T p.D1455Y (on ENST00000272643; = p.D1453Y on NM_001316349.2) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55652802; called by muse, mutect2, varscan2
- TM4SF19 | c.239G>A p.W80* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV56556138; called by muse, mutect2, varscan2
- ZZEF1 | c.7945A>C p.M2649L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV67555886; called by muse, mutect2
- COQ8B | c.718-5_718-3del | Splice Region (DEL) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- OTOF | c.1054_1061del p.F352Qfs*7 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- QSER1 | c.1521del p.S508Hfs*30 (on ENST00000399302; = p.S637Hfs*30 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 40/287 reads (14%) | called by pindel, varscan2
- SEC23B | c.261_262del p.F87Lfs*16 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | called by mutect2, pindel, varscan2
- TREML4 | c.303del p.N102Mfs*49 | Frame Shift Del (DEL) | VAF 27/166 reads (16%) | called by mutect2, pindel, varscan2
- ZNF594 | c.1761_1762dup p.V588Gfs*2 | Frame Shift Ins (INS) | VAF 68/374 reads (18%) | called by mutect2, varscan2
- ZXDA | c.1027_1029del p.T343del | In Frame Del (DEL) | VAF 9/53 reads (17%) | called by pindel, varscan2
- DMD | c.447T>C p.R149= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV55853228; called by muse, mutect2, varscan2
- HCN3 | c.1495A>C p.R499= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV61360329; called by muse, mutect2, varscan2
- HES1 | c.33G>A p.S11= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV51683712; called by muse, varscan2
- NCOA6 | c.5247G>T p.T1749= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV62861243; called by muse, mutect2, varscan2
- RUNX3 | c.243G>T p.S81= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1364012153, COSV58242363; called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516065 G>T | 5'Flank (SNP) | VAF 31/96 reads (32%) | catalogued as rs765282159, COSV53062507; called by muse, mutect2, varscan2
